Gene-level copy-number profile of specimen HCM-BROD-0414-C25-85M from HCMI case HCM-BROD-0414-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 53.8 years (19,635 days).
Specimen HCM-BROD-0414-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e4ed30ea-b9e2-4877-83fb-353679682905.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0414-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/acb5c87a-604c-4d93-8446-4d53f2ee488b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,146; copy number 1: 19,337; copy number 2: 34,364; copy number 3: 3,939; copy number 4: 58; copy number 5: 15; copy number 7: 27; copy number 8: 21.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:2,536,647–2,732,573, 1 gene (within-gene range 0–4): FAM193A.
- chr4:2,741,648–4,157,443, 41 genes: TNIP2, SH3BP2, ADD1, AL121750.1, MFSD10, NOP14-AS1, NOP14, GRK4, HTT, RNU6-204P, HTT-AS, AL390065.2, AL390065.1, MSANTD1, RGS12, AL645949.1, AL645949.2, HGFAC, DOK7, LRPAP1, AL590235.1, LINC00955, AL121796.1, LINC02171, LINC02600, ADRA2C, OR7E163P, OR7E162P, AC147876.1, AC226119.1, AC226119.2, ALG1L7P, FAM86EP, ENPP7P9, AC116562.3, RPS3AP16, AC116562.2, AC116562.1, OR7E103P, UNC93B4, OR7E99P.
- chr4:20,528,275–20,528,384, 1 gene (within-gene range 0–2): MIR218-1.
- chr4:49,523,648–49,524,185, 2 genes: AC119751.2, AC119751.8.
- chr4:49,561,285–49,589,529, 4 genes: AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 63 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–499,156, 21 genes, copy number 8: BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571, AC092574.2, ZNF519P4, AC092574.1, ABCA11P, ZNF721.
- chr4:1,056,250–1,982,207, 27 genes, copy number 7 (within-gene range 4–7): RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2.
- chr15:21,293,653–21,307,855, 2 genes, copy number 5: AC068446.1, RNU6-1235P.
- chr15:30,344,307–30,517,867, 13 genes, copy number 5: AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2.

Autosomal genes at a single copy (total copy number 1): 17,582. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
